Somatic mutation profile of tumor specimen C3L-00947-01 (aliquot CPT0027420009) from CPTAC case C3L-00947, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.2 years (26,010 days).
Specimen C3L-00947-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32b1cfa9-b1bf-4fa6-82f3-69a6123588a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00947-71 (Blood Derived Normal), aliquot CPT0027480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee8a4980-0d7e-4e3d-978c-365f4cc376c9

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Nonsense Mutation 6, Intron 3, 5'UTR 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 149/383 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 108/289 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- GALNS | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs118204448, CM1410235, CM950535, COSV51938223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 89/282 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAD2 | c.1043G>A p.R348H (on ENST00000315906 / NM_001145400.2; = p.R430H on NM_139174.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763031674, COSV51895002; called by mutect2, varscan2
- ALDH7A1 | c.33C>G p.H11Q | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs753485531; called by muse, mutect2, varscan2
- APAF1 | c.3388G>T p.V1130L (on ENST00000551964 / NM_181861.2; = p.V1076L on NM_001160.3) | Missense Mutation (SNP) | VAF 53/496 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99044699; called by muse, mutect2, varscan2
- CDC45 | c.331_333del p.N111del | In Frame Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs1378094381; called by mutect2, pindel, varscan2
- DICER1 | c.4420A>G p.T1474A | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58615369; called by muse, mutect2, varscan2
- DNMT3B | c.204G>A p.Q68= | Splice Region (SNP) | VAF 215/528 reads (41%) | catalogued as rs777231550; called by muse, mutect2, varscan2
- ERBB3 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 155/433 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as COSV57247034, COSV99915945; called by muse, mutect2, varscan2
- MUC12 | c.1319C>A p.A440D (on ENST00000379442; = p.A297D on NM_001164462.1) | Missense Mutation (SNP) | VAF 151/382 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); catalogued as COSV101059733; called by muse, mutect2, varscan2
- NCKAP1L | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as COSV53206550; called by muse, mutect2
- NEU4 | c.1276G>A p.G426R (on ENST00000391969 / NM_001167602.3; = p.G438R on NM_080741.4) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.608); catalogued as rs370021042; called by muse, mutect2, varscan2
- PAMR1 | c.1586G>A p.R529Q (on ENST00000619888 / NM_001001991.3; = p.R546Q on NM_015430.4) | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs767807537; called by muse, mutect2, varscan2
- PCDHB5 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV50652640; called by muse, mutect2, varscan2
- SGO2 | c.1929dup p.G644Rfs*2 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs1260834379; called by mutect2, varscan2
- SHPK | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs138595855; called by muse, mutect2, varscan2
- SPTAN1 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs1564223801, COSV63989170; called by muse, mutect2, varscan2
- TRPV2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 171/446 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58428263; called by muse, mutect2, varscan2
- UBA6 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1013766853; called by muse, mutect2, varscan2
- ZFHX3 | c.5623G>T p.E1875* | Nonsense Mutation (SNP) | VAF 11/209 reads (5%) | catalogued as COSV51734706; called by muse, mutect2
- ZNF716 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 164/422 reads (39%) | catalogued as rs1554321361, COSV70779933; called by muse, mutect2, varscan2
- BCORL1 | c.1259T>G p.V420G | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CR1 | c.856T>C p.W286R (on ENST00000367051; = p.W736R on NM_000573.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DPEP1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ERICH6 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FBXL16 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GLI2 | c.2447G>A p.R816H (on ENST00000361492 / NM_001374353.1; = p.R833H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GNAS | c.446C>A p.P149Q | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- GRB2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 136/177 reads (77%) | called by muse, mutect2, varscan2
- IRX2 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- JUND | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- KRT1 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.22); called by muse, mutect2
- LMCD1 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, varscan2
- MUC16 | c.6397G>A p.E2133K | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PLXND1 | c.4505_4509del p.M1502Kfs*40 | Frame Shift Del (DEL) | VAF 78/188 reads (41%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.1610T>A p.I537N | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCG | c.2068A>G p.S690G | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RPP25 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRM2 | c.846C>G p.H282Q | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHC2 | c.480C>A p.C160* | Nonsense Mutation (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- SPATS2 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPATS2 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIE1 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); called by muse, mutect2
- WWP1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX3 | c.7605dup p.K2536* | Frame Shift Ins (INS) | VAF 103/275 reads (37%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.5752A>T p.K1918* | Nonsense Mutation (SNP) | VAF 45/266 reads (17%) | called by muse, mutect2, varscan2
- ZNF189 | c.1768del p.H590Mfs*4 | Frame Shift Del (DEL) | VAF 66/240 reads (28%) | called by mutect2, pindel, varscan2
- ZNF2 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF423 | c.2980G>T p.D994Y (on ENST00000563137 / NM_001379286.1; = p.D986Y on NM_015069.4) | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AGBL5 | c.354C>T p.R118= | Silent (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- BIN1 | c.1440G>A p.T480= (on ENST00000316724 / NM_001320642.1; = p.T341= on NM_004305.4) | Silent (SNP) | VAF 173/497 reads (35%) | catalogued as rs754900286; called by muse, mutect2, varscan2
- C2orf81 | c.156G>A p.A52= | Silent (SNP) | VAF 131/343 reads (38%) | called by muse, mutect2, varscan2
- CD7 | c.36G>C p.L12= | Silent (SNP) | VAF 117/154 reads (76%) | called by muse, mutect2, varscan2
- CYLC1 | c.315T>G p.T105= | Silent (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.1461C>T p.H487= | Silent (SNP) | VAF 100/278 reads (36%) | catalogued as rs782325556; called by muse, mutect2, varscan2
- KRT86 | c.651C>T p.C217= | Silent (SNP) | VAF 185/486 reads (38%) | catalogued as rs377005978; called by muse, mutect2, varscan2
- NPAS3 | c.2340G>A p.A780= (on ENST00000356141 / NM_001164749.2; = p.A748= on NM_022123.3) | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as rs981692072; called by muse, mutect2, varscan2
- PADI2 | c.1728C>T p.D576= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as rs375561378, COSV64954365; called by muse, mutect2, varscan2
- PTPN23 | c.1710C>T p.R570= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as rs751034059; called by muse, mutect2, varscan2
- TRPM6 | c.4347A>T p.G1449= | Silent (SNP) | VAF 274/650 reads (42%) | called by muse, mutect2, varscan2
- GRHL1 | c.-78G>T | 5'UTR (SNP) | VAF 10/236 reads (4%) | catalogued as rs1256953634, COSV61410381; called by muse, mutect2
- PCDHGA3 | c.2425-66587C>T | Intron (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- SERPINI1 | c.980-19del | Intron (DEL) | VAF 30/110 reads (27%) | catalogued as COSV55510723; called by mutect2, pindel, varscan2
- TUBA8 | c.376-45G>A | Intron (SNP) | VAF 68/176 reads (39%) | catalogued as rs755265426; called by muse, mutect2, varscan2
- ZNF257 | c.-24C>T | 5'UTR (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
